TCGA case TCGA-UZ-A9PL — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of California San Francisco. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e0c97b37-9834-4811-981e-dcb8982dba44

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; AJCC staging edition: 6th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,152 days (8.6 years).
   Pathology details: Consistent pathology review: Yes.

Follow-up (3 entries)
- Days to follow up: 3,152 days (8.6 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0.
- Follow-up contact recording only the day: day 0.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UZ-A9PL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,420 mg.
  Slide TCGA-UZ-A9PL-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-UZ-A9PL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UZ-A9PL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lymph nodes examined: No; Tobacco smoking history indicator: 1.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,152 days; disease-specific survival: no event (censored), 3,152 days; disease-free interval: no event (censored), 3,152 days; progression-free interval: no event (censored), 3,152 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UZ-A9PL-01A-11D-A381-01): tumor purity 0.86, ploidy 2.13, whole-genome doublings 0.
